TCGA case TCGA-DD-AAW3 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/564b4f4d-3c18-40d5-9d95-916774df600c

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: South Korea; Age at index: 69 years; Vital status: Alive.

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 69.1 years (25,254 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,633 days (4.5 years); Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 1,451 days (4.0 years); Disease response: Tumor Free.
- Days to follow up: 1,633 days (4.5 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- Alpha Fetoprotein 3 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 15].
- Albumin 4.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.3; Blood test normal range upper: 5.2].
- Creatinine 1 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.4].
- Platelets 241 (unit not recorded by GDC) [Blood test normal range lower: 130; Blood test normal range upper: 400].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.2; Blood test normal range upper: 1.2].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 162 cm; BMI: 24.4.

Family history
- Relatives with cancer history count: 1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-AAW3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-DD-AAW3-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-DD-AAW3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-AAW3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Segmentectomy, Single; New tumor event diagnosis indicator: No.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,633 days; disease-specific survival: no event (censored), 1,633 days; disease-free interval: no event (censored), 1,633 days; progression-free interval: no event (censored), 1,633 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-AAW3-01A-11D-A40O-01): tumor purity 0.86, ploidy 2.19, whole-genome doublings 0.
